Somatic mutation profile of tumor specimen C3L-03405-01 (aliquot CPT0224600009) from CPTAC case C3L-03405, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.2 years (21,614 days).
Specimen C3L-03405-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e89c7d7-e2fa-4fa7-861e-5717ee99efdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03405-31 (Blood Derived Normal), aliquot CPT0226240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40d16448-5086-4214-b940-1a333cd44422

The open-access MAF lists 71 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 19, Nonsense Mutation 3, Intron 3, In Frame Del 1, Splice Site 1, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1214_1216del p.I405del (on ENST00000521381 / NM_181523.3; = p.I135del on NM_181504.4) | In Frame Del (DEL) | VAF 32/70 reads (46%) | hotspot (GDC flag); called by pindel, varscan2
- ANKRD30A | c.1205C>T p.T402I (on ENST00000611781; = p.T346I on NM_052997.2) | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as rs565638896; called by muse, mutect2, varscan2
- CEACAM5 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782504876; called by muse, mutect2, varscan2
- CEP295 | c.5045dup p.S1683Kfs*2 | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | catalogued as rs762289202; called by mutect2, varscan2
- COL4A4 | c.5029C>T p.R1677C | Missense Mutation (SNP) | VAF 121/402 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759631057, CM074108, COSV61629349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTCFL | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772424129, COSV54770682; called by muse, mutect2, varscan2
- DNAH17 | c.7169C>T p.S2390L | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs368286264; called by muse, mutect2, varscan2
- DSP | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 128/457 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs200250096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRE | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 84/132 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1337854518; called by muse, mutect2, varscan2
- GPA33 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs373880766; called by muse, mutect2, varscan2
- GYS1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs760809851, COSV54404786; called by muse, mutect2, varscan2
- HLA-B | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 103/397 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as rs139817031; called by muse, mutect2
- KCNJ5 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772551729, COSV57970468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC4 | c.6151G>T p.V2051F | Missense Mutation (SNP) | VAF 138/1221 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as rs774017070; called by mutect2, varscan2
- MYO7B | c.4262G>A p.R1421H | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs372450782; called by muse, mutect2, varscan2
- NPFFR2 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs750736231; called by muse, mutect2, varscan2
- PRAMEF11 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 181/810 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); catalogued as rs916603707, COSV70819819; called by muse, mutect2, varscan2
- RUSC2 | c.2843G>A p.G948D | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs773276905; called by muse, mutect2, varscan2
- SLC8A2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 174/466 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776379610, COSV52638770, COSV52642416; called by muse, mutect2, varscan2
- TMEM214 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs1174421948; called by muse, mutect2, varscan2
- TRIM4 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as rs139121700; called by muse, mutect2, varscan2
- VWA7 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777773004, COSV100991974; called by muse, mutect2, varscan2
- ZDHHC18 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774787807; called by muse, mutect2, varscan2
- ZNF266 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as rs780087634, COSV63222304; called by muse, mutect2, varscan2
- AKAP9 | c.10030C>T p.R3344W (on ENST00000359028; = p.R3320W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AOPEP | c.1863del p.L622Ffs*66 (on ENST00000375315 / NM_001193329.1; = p.L523Ffs*66 on NM_032823.5) | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- AP1M1 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AP3B1 | c.2470+1G>A p.X824_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | called by muse, varscan2
- BAZ2A | c.4079T>C p.M1360T | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALHM5 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFHR5 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CPT2 | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CX3CL1 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYRK2 | c.430G>T p.E144* (on ENST00000344096 / NM_006482.3; = p.E71* on NM_003583.4) | Nonsense Mutation (SNP) | VAF 29/200 reads (15%) | called by muse, mutect2, varscan2
- DYRK2 | c.1276G>C p.D426H (on ENST00000344096 / NM_006482.3; = p.D353H on NM_003583.4) | Missense Mutation (SNP) | VAF 72/548 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DZIP1 | c.1951A>G p.T651A (on ENST00000347108; = p.T632A on NM_014934.5) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM83H | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.637); called by muse, mutect2
- IGSF23 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 129/426 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MUC16 | c.36347A>G p.N12116S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NDUFAF7 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR5K4 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PCDHB5 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 125/216 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLEKHB2 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PRR36 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT deleterious (0.01); called by muse, mutect2
- PTPRO | c.2542C>T p.H848Y | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- TFAP2E | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- TMEM120B | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- WSCD2 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADAD2 | c.321G>A p.P107= | Silent (SNP) | VAF 121/349 reads (35%) | catalogued as rs1016956518; called by muse, mutect2, varscan2
- ANGPT2 | c.411G>A p.E137= | Silent (SNP) | VAF 57/231 reads (25%) | catalogued as rs1460353319, COSV57340093; called by muse, mutect2, varscan2
- DOCK8 | c.873C>T p.Y291= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs369844425; called by muse, mutect2, varscan2
- FBN1 | c.6636G>A p.Q2212= | Silent (SNP) | VAF 84/271 reads (31%) | called by muse, mutect2, varscan2
- FRAS1 | c.9903T>C p.S3301= | Silent (SNP) | VAF 58/169 reads (34%) | called by muse, mutect2, varscan2
- FRMPD4 | c.3459C>T p.D1153= | Silent (SNP) | VAF 83/121 reads (69%) | catalogued as rs1427946992, COSV66215045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GEMIN4 | c.834G>A p.S278= | Silent (SNP) | VAF 106/339 reads (31%) | catalogued as rs1005122571, COSV56747571; called by muse, mutect2, varscan2
- INSRR | c.3693G>A p.P1231= | Silent (SNP) | VAF 105/306 reads (34%) | catalogued as rs1344292641; called by muse, mutect2, varscan2
- KLF17 | c.549G>A p.S183= | Silent (SNP) | VAF 91/316 reads (29%) | catalogued as rs759531219, COSV64856884; called by muse, mutect2, varscan2
- MED13 | c.4521A>G p.A1507= | Silent (SNP) | VAF 67/276 reads (24%) | catalogued as rs529840872; called by muse, mutect2, varscan2
- MUC12 | c.144C>T p.V48= | Silent (SNP) | VAF 48/243 reads (20%) | catalogued as rs76074645; called by muse, mutect2, varscan2
- NACAD | c.1878G>A p.V626= | Silent (SNP) | VAF 66/372 reads (18%) | called by muse, varscan2
- PCDHB2 | c.1857G>C p.V619= | Silent (SNP) | VAF 193/1033 reads (19%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.3372C>T p.S1124= | Silent (SNP) | VAF 95/347 reads (27%) | catalogued as rs760760043, COSV100651617; called by muse, mutect2, varscan2
- PYGB | c.1629G>A p.K543= | Silent (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- SATB2 | c.2055C>T p.D685= | Silent (SNP) | VAF 50/505 reads (10%) | catalogued as rs747832215, COSV53492775; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A12 | c.1917C>T p.Y639= | Silent (SNP) | VAF 103/329 reads (31%) | catalogued as rs375503729; called by muse, mutect2, varscan2
- TMEM168 | c.159C>T p.Y53= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs760501116; called by mutect2, varscan2
- VCX | c.303C>T p.H101= | Silent (SNP) | VAF 304/765 reads (40%) | catalogued as rs151212725, COSV58232329; called by muse, varscan2
- CCP110 | c.2900+20G>A | Intron (SNP) | VAF 62/114 reads (54%) | called by muse, mutect2, varscan2
- CHPF2 | c.-1253G>A | 5'UTR (SNP) | VAF 98/454 reads (22%) | catalogued as rs1195675690; called by muse, mutect2, varscan2
- FMN1 | c.2044-2552G>A | Intron (SNP) | VAF 74/300 reads (25%) | catalogued as rs570854143, COSV100569176; called by muse, mutect2, varscan2
- MSR1 | c.1033+2526C>T | Intron (SNP) | VAF 9/213 reads (4%) | catalogued as rs903097728; called by muse, mutect2
